Somatic mutation profile of tumor specimen MP2PRT-PAUTUX-TMP1-A (aliquot MP2PRT-PAUTUX-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUTUX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (654 days).
Specimen MP2PRT-PAUTUX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 596ccb18-34ed-4b93-b0fa-85a0424f3e87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTUX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTUX-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61d2f62c-a70a-476c-bca6-4cdc55913206

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 3, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBA2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs770032885, COSV67104537; called by muse, mutect2
- ARHGAP22 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 60/826 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV50985181, COSV99984982; called by muse, mutect2
- CEP290 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 23/399 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1004217500; called by muse, mutect2
- EPOR | c.1202C>G p.S401* | Nonsense Mutation (SNP) | VAF 43/454 reads (9%) | catalogued as COSV55800044; called by muse, mutect2, varscan2
- ERF | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 35/564 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.206); catalogued as COSV55896880, COSV55897929; called by muse, mutect2
- FAM71C | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100175813; called by muse, mutect2
- FCRL1 | c.195G>C p.W65C | Missense Mutation (SNP) | VAF 47/500 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63826680; called by muse, mutect2
- GABRA1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195805; called by muse, mutect2
- GC | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV99909708; called by muse, mutect2
- GRAMD1A | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765331104, COSV58767703; called by muse, mutect2
- GRM6 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 43/449 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as rs780673214, COSV51444663; called by muse, mutect2, varscan2
- H2BC3 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV63550971; called by muse, mutect2, varscan2
- KIAA2013 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 188/511 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs754796277; called by muse, mutect2, varscan2
- MDC1 | c.5798G>A p.R1933Q | Missense Mutation (SNP) | VAF 67/642 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs536243116, COSV64523145; called by muse, mutect2, varscan2
- SIPA1L1 | c.5172G>A p.M1724I | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1304991609; called by muse, mutect2, varscan2
- TBC1D5 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1303977846; called by muse, mutect2
- TBC1D8B | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99344533; called by muse, mutect2
- TENT4A | c.1562C>A p.S521Y | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.655); catalogued as COSV50094912, COSV50100243; called by muse, mutect2, varscan2
- TRABD | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.202); catalogued as rs370115508; called by muse, mutect2
- UNC13A | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV53211577; called by muse, mutect2
- VWDE | c.2971G>C p.D991H | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51734523; called by muse, mutect2, varscan2
- ZBTB7C | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 55/473 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as COSV59690786; called by muse, mutect2, varscan2
- AARS1 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ACAA2 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATXN3L | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2
- COPB2 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2
- CTC1 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- FBN2 | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- FCHO1 | c.2386G>C p.E796Q | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- FPR3 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIPC3 | c.3848C>G p.S1283* | Nonsense Mutation (SNP) | VAF 46/616 reads (7%) | called by muse, mutect2
- GIPC3 | c.4009C>G p.L1337V | Missense Mutation (SNP) | VAF 55/561 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2
- IARS1 | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- LYRM1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MGAM2 | c.6211G>T p.D2071Y | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- MOGAT2 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MUC16 | c.13246C>A p.P4416T | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.412); called by muse, mutect2
- NCOR2 | c.2028G>C p.E676D | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NRP1 | c.2727G>C p.L909F | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR1A1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PDCD4 | c.968C>G p.S323C | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PPFIA2 | c.3605C>A p.P1202H | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC12A2 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2
- TARS3 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTBK1 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 31/616 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UBE3D | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13C | c.385+1G>A p.X129_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- VTCN1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.376); called by muse, mutect2
- ABHD17C | c.306C>G p.R102= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- AC090517.4 | c.1320C>G p.L440= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- ADGRF4 | c.768C>G p.L256= | Silent (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- ALDH1B1 | c.147C>T p.V49= | Silent (SNP) | VAF 53/427 reads (12%) | catalogued as rs1409011618; called by muse, mutect2, varscan2
- CENPI | c.1335C>G p.L445= | Silent (SNP) | VAF 148/387 reads (38%) | catalogued as COSV99515171; called by muse, mutect2, varscan2
- EBLN1 | c.345T>G p.T115= | Silent (SNP) | VAF 15/352 reads (4%) | called by muse, mutect2
- ETAA1 | c.102G>A p.R34= | Silent (SNP) | VAF 60/729 reads (8%) | called by muse, mutect2
- GOPC | c.546G>A p.L182= | Silent (SNP) | VAF 17/374 reads (5%) | catalogued as COSV50005044; called by muse, mutect2
- L1CAM | c.3426C>T p.F1142= | Silent (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- NFATC2 | c.1794C>T p.L598= | Silent (SNP) | VAF 25/424 reads (6%) | called by muse, mutect2
- PEPD | c.1041G>C p.L347= | Silent (SNP) | VAF 50/640 reads (8%) | catalogued as rs1226563721; called by muse, mutect2
- POGLUT2 | c.54C>G p.L18= | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2, varscan2
- SMG8 | c.2196G>A p.K732= | Silent (SNP) | VAF 40/348 reads (11%) | catalogued as COSV99958941; called by muse, mutect2, varscan2
- DCAF13 | c.-29C>G | 5'UTR (SNP) | VAF 30/503 reads (6%) | catalogued as rs762435482, COSV52569558; called by muse, mutect2
